Somatic mutation profile of tumor specimen TCGA-34-5241-01A (aliquot TCGA-34-5241-01A-01D-1441-08) from TCGA case TCGA-34-5241, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 79.7 years (29,098 days).
Specimen TCGA-34-5241-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d22edc66-721d-4d1a-98fe-b27cdb3c41c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-5241-10A (Blood Derived Normal), aliquot TCGA-34-5241-10A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a296ef11-705f-4e8d-a5e0-40ba8e35195d

The open-access MAF lists 208 somatic variants for this specimen: 154 protein-altering or splice-affecting, 52 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 52, Nonsense Mutation 12, Splice Site 4, Frame Shift Del 2, Frame Shift Ins 2, Splice Region 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG4 | c.1778T>C p.L593S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100266570; called by muse, mutect2
- ABTB1 | c.644-2A>T p.X215_splice (on ENST00000232744 / NM_172027.3; = p.X73_splice on NM_032548.3) | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99229627; called by muse, mutect2, varscan2
- AC092143.1 | c.1897G>T p.V633L | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100205656, COSV100205888, COSV59248993; called by muse, mutect2, varscan2
- ADAM22 | c.2706G>A p.W902* (on ENST00000265727 / NM_001324420.2; = p.W866* on NM_016351.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/241 reads (6%) | catalogued as COSV99716034; called by muse, mutect2
- ADAMTS3 | c.2456G>T p.S819I | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54406299; called by muse, mutect2, varscan2
- ADCY5 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 24/123 reads (20%) | catalogued as rs1553727462, COSV100567398; called by muse, mutect2, varscan2
- ADGRE3 | c.1283A>G p.Y428C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505903; called by muse, mutect2, varscan2
- AGTPBP1 | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV100429349, COSV100430015; called by muse, mutect2, varscan2
- AKAP3 | c.768G>T p.E256D | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.404); catalogued as COSV99961849; called by muse, mutect2, varscan2
- ARHGEF12 | c.4126G>C p.D1376H | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV100754709; called by muse, mutect2, varscan2
- ARIH1 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs147408829; called by muse, mutect2, varscan2
- ATP6V1B1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99313833; called by muse, mutect2, varscan2
- BMP1 | c.2467G>A p.G823R | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100114624; called by muse, mutect2, varscan2
- BTLA | c.662C>G p.S221* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as COSV100569630; called by muse, mutect2, varscan2
- BTN3A2 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.985); catalogued as rs547225553, COSV100709581; called by muse, mutect2, varscan2
- C10orf53 | c.290C>G p.P97R | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); catalogued as COSV100934999; called by muse, mutect2, varscan2
- C9orf64 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100123505; called by muse, mutect2, varscan2
- CAMK1D | c.1039+3G>T | Splice Region (SNP) | VAF 18/243 reads (7%) | catalogued as COSV101123521; called by muse, mutect2
- CCDC88A | c.3148G>C p.E1050Q | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99709896; called by muse, mutect2
- CCT8L2 | c.1200C>A p.F400L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV100742586, COSV63463290; called by muse, mutect2, varscan2
- CD84 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100245845; called by muse, mutect2, varscan2
- CDH10 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV100050362; called by muse, mutect2, varscan2
- CENPL | c.271T>A p.Y91N | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100616266; called by muse, mutect2
- CERKL | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100183242; called by muse, mutect2, varscan2
- CFAP221 | c.1216T>C p.Y406H | Missense Mutation (SNP) | VAF 34/654 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99732044; called by muse, mutect2
- CLCA4 | c.2347G>C p.V783L | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.101); catalogued as COSV100991070; called by muse, mutect2, varscan2
- CNGB3 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 78/416 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100181403, COSV100181425; called by muse, mutect2, varscan2
- COL21A1 | c.1877G>T p.G626V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777710; called by muse, mutect2
- COL22A1 | c.3151-1G>T p.X1051_splice | Splice Site (SNP) | VAF 28/166 reads (17%) | catalogued as COSV57336752; called by muse, mutect2, varscan2
- CPPED1 | c.125A>C p.Q42P | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99902837; called by muse, mutect2, varscan2
- CSMD1 | c.5778C>G p.I1926M (on ENST00000520002; = p.I1925M on NM_033225.6) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100144803, COSV59360516; called by muse, mutect2
- DACT1 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV100241638; called by muse, mutect2, varscan2
- DCANP1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.14); catalogued as COSV72345950; called by muse, mutect2, varscan2
- DCUN1D3 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV100176743, COSV60952743; called by muse, mutect2, varscan2
- DENND4C | c.1044C>A p.H348Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100991222; called by muse, varscan2
- DLG2 | c.2609T>A p.L870* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV99713127; called by muse, varscan2
- DYNC1H1 | c.8555C>T p.T2852M | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs575806819, COSV100794575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPG5 | c.580A>T p.N194Y | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99956655; called by muse, mutect2, varscan2
- ERRFI1 | c.505T>C p.C169R | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV66310619; called by muse, mutect2
- EXO1 | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100799646; called by muse, mutect2, varscan2
- EXOC5 | c.1717A>G p.T573A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100566992; called by muse, mutect2
- EXPH5 | c.3434C>T p.S1145L | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.315); catalogued as COSV56207429; called by muse, mutect2, varscan2
- EYA4 | c.218T>A p.M73K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.271); catalogued as COSV100765317; called by muse, mutect2, varscan2
- F11R | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99230829; called by muse, mutect2, varscan2
- FBF1 | c.2560G>A p.E854K (on ENST00000586717; = p.E868K on NM_001319193.1) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs770676010, COSV100044822; called by muse, mutect2, varscan2
- FFAR3 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 22/373 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100588138; called by muse, mutect2
- GAS2L1 | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.077); catalogued as COSV53329978, COSV99329421; called by muse, mutect2, varscan2
- HCN1 | c.1493C>G p.P498R | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100298999, COSV57533136; called by muse, mutect2
- HECW2 | c.1363A>T p.T455S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99646119; called by muse, mutect2, varscan2
- HEPH | c.3032A>T p.Y1011F (on ENST00000343002; = p.Y744F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.405); catalogued as COSV100294266; called by muse, mutect2, varscan2
- HSP90AA1 | c.158C>G p.S53* | Nonsense Mutation (SNP) | VAF 9/96 reads (9%) | catalogued as COSV99355088; called by muse, mutect2
- IL1RL2 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99960322; called by muse, mutect2
- INHA | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV99216376; called by muse, mutect2, varscan2
- IRF7 | c.808G>A p.E270K (on ENST00000397566; = p.E257K on NM_001572.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.182); catalogued as rs1160609325, COSV52750603, COSV52757118, COSV99199614; called by muse, mutect2
- ITPR2 | c.6803G>A p.W2268* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV101189853; called by muse, mutect2, varscan2
- KIFC2 | c.632A>G p.Q211R | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.374); catalogued as COSV100023608; called by muse, mutect2
- LARGE1 | c.1572G>T p.M524I | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV100504785, COSV61665244; called by muse, varscan2
- LATS1 | c.1232T>C p.V411A | Missense Mutation (SNP) | VAF 38/423 reads (9%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.01); catalogued as COSV99485426; called by muse, mutect2
- LIG4 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 64/671 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.644); catalogued as rs139785910, COSV100799726; called by muse, mutect2
- LIMD1 | c.73A>G p.K25E | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99836808; called by muse, mutect2, varscan2
- LRP2 | c.3879C>A p.D1293E | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV99786868; called by muse, mutect2, varscan2
- LRRC7 | c.1489G>A p.V497I (on ENST00000651989 / NM_001370785.2; = p.V464I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV99224947; called by muse, mutect2, varscan2
- MAN1C1 | c.1306A>G p.I436V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.385); catalogued as rs1362240122, COSV99847898; called by muse, mutect2, varscan2
- MEGF8 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs769196067, COSV52079924; called by muse, mutect2, varscan2
- MS4A6A | c.148-1G>C p.X50_splice | Splice Site (SNP) | VAF 18/76 reads (24%) | catalogued as COSV100124580; called by muse, mutect2, varscan2
- MTNR1A | c.266T>C p.F89S | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV100208112; called by muse, mutect2, varscan2
- NISCH | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.178); catalogued as COSV100617170; called by muse, mutect2, varscan2
- NLGN1 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100848814; called by muse, mutect2, varscan2
- NUP205 | c.3436G>A p.D1146N | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99606562; called by muse, mutect2, varscan2
- OPRPN | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.045); catalogued as COSV101271079; called by muse, mutect2, varscan2
- OR2AK2 | c.611T>A p.L204H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100823252, COSV63550597; called by muse, mutect2, varscan2
- OR2L8 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61727025; called by muse, mutect2, varscan2
- OR2M3 | c.6_7insC p.R3Qfs*109 | Frame Shift Ins (INS) | VAF 57/336 reads (17%) | catalogued as COSV101513402; called by mutect2, pindel, varscan2
- OR52K2 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100355654; called by muse, mutect2
- OR5T1 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV57301542; called by muse, mutect2
- OR6A2 | c.907A>T p.K303* | Nonsense Mutation (SNP) | VAF 10/136 reads (7%) | catalogued as COSV100215623; called by muse, mutect2
- OR8D1 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1209799390, COSV100766552; called by muse, mutect2
- ORC3 | c.1008C>G p.F336L | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100005700; called by muse, mutect2, varscan2
- PCDH15 | c.5456C>G p.P1819R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV100216701; called by muse, mutect2, varscan2
- PCLO | c.8059C>G p.P2687A | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100428371, COSV61614828; called by muse, mutect2
- PCNX4 | c.3226G>A p.E1076K (on ENST00000406854 / NM_001330177.2; = p.E842K on NM_022495.5) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100469998; called by muse, mutect2, varscan2
- PCSK5 | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101377298; called by muse, mutect2, varscan2
- PLCG2 | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.518); catalogued as rs199703276, COSV100842098; called by muse, mutect2, varscan2
- PLCH1 | c.4027G>T p.D1343Y (on ENST00000340059 / NM_001130960.2; = p.D1335Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); catalogued as COSV100395869, COSV58200927; called by muse, mutect2, varscan2
- PLEKHO1 | c.491G>C p.R164P | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99215144; called by muse, mutect2
- PLGRKT | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV99803558; called by muse, mutect2, varscan2
- PLIN4 | c.2668G>A p.G890R (on ENST00000301286; = p.G905R on NM_001367868.2) | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs777252501, COSV100012833; called by muse, mutect2
- PLSCR4 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs768132771, COSV100724133; called by muse, mutect2, varscan2
- POLE | c.3137A>G p.Y1046C | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100265613; called by muse, mutect2
- PRR30 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99574341; called by muse, mutect2, varscan2
- PTGIS | c.494T>A p.L165H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99720717; called by muse, mutect2, varscan2
- PTH2R | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as COSV99782166; called by muse, varscan2
- PTPRD | c.5381A>G p.D1794G | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV100643759; called by muse, mutect2, varscan2
- RABEP2 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs184703556, COSV100706864; called by muse, mutect2, varscan2
- REG1A | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV52068898, COSV52071880; called by muse, mutect2, varscan2
- RNASE3 | c.208T>A p.F70I | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100484198; called by muse, mutect2
- ROS1 | c.4696A>G p.T1566A | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100876592; called by muse, mutect2, varscan2
- RUNX1T1 | c.1654G>T p.G552* (on ENST00000265814 / NM_001198628.1; = p.G525* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV56149134, COSV99749926; called by muse, mutect2, varscan2
- RYR1 | c.5453C>T p.A1818V | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs1274823763, COSV62092082, COSV62113411; called by muse, mutect2
- SAYSD1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV100010074; called by muse, mutect2, varscan2
- SCAF8 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100913961; called by muse, mutect2, varscan2
- SHTN1 | c.1378A>T p.T460S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99598583; called by muse, mutect2, varscan2
- SLC15A1 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100918183; called by muse, mutect2, varscan2
- SLC4A1AP | c.1473G>C p.K491N | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100389199; called by muse, mutect2, varscan2
- SLC4A5 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100697449; called by muse, varscan2
- SLC7A3 | c.1376G>T p.W459L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99979382; called by muse, mutect2, varscan2
- SMARCA2 | c.1280G>C p.R427P | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100570457, COSV61807785; called by muse, mutect2, varscan2
- SNX33 | c.926G>T p.R309I | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV100145734; called by muse, mutect2
- SNX6 | c.485G>A p.R162H (on ENST00000652385; = p.R34H on NM_021249.5) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs762864087, COSV100751411; called by muse, mutect2, varscan2
- SP140 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100613463; called by muse, mutect2
- SPHKAP | c.2964C>A p.S988R | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV60874764, COSV60877069; called by muse, mutect2, varscan2
- STYK1 | c.1258A>G p.S420G | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV99311635; called by muse, mutect2, varscan2
- SUPT5H | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 102/219 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100781941; called by muse, mutect2, varscan2
- SYCP1 | c.2141T>C p.M714T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101050793; called by muse, mutect2, varscan2
- TAL1 | c.914C>A p.T305K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs766220223, COSV99595924; called by muse, mutect2, varscan2
- TDRD10 | c.491C>G p.P164R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV100872999; called by muse, mutect2, varscan2
- TEX10 | c.2504T>G p.L835R | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.08); catalogued as COSV99317205; called by muse, mutect2, varscan2
- TEX10 | c.2503C>A p.L835I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as COSV52442085, COSV99317206; called by muse, mutect2, varscan2
- THOC5 | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 70/399 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs760121204, COSV100803474; called by muse, mutect2, varscan2
- TMEM127 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs144326855; ClinVar: uncertain significance; called by muse, mutect2
- TMEM89 | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as rs201320379, COSV100258102; called by muse, mutect2, varscan2
- TNFSF13B | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV101022325; called by muse, mutect2
- TNN | c.2425A>G p.T809A | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV99511276; called by muse, mutect2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 36/88 reads (41%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TTC17 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as COSV99234832; called by muse, mutect2, varscan2
- TTN | c.63126G>T p.K21042N (on ENST00000591111; = p.K13618N on NM_003319.4) | Missense Mutation (SNP) | VAF 32/146 reads (22%) | PolyPhen probably damaging (0.997); catalogued as rs941771270, COSV100598402; called by muse, mutect2, varscan2
- TTN | c.57493G>T p.D19165Y (on ENST00000591111; = p.D11741Y on NM_003319.4) | Missense Mutation (SNP) | VAF 21/302 reads (7%) | PolyPhen probably damaging (0.944); catalogued as COSV100598404; called by muse, mutect2
- TTN | c.17437A>G p.T5813A (on ENST00000591111; = p.T4886A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | PolyPhen benign (0.01); catalogued as COSV100598408; called by muse, mutect2, varscan2
- TUBB1 | c.150C>A p.Y50* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99413938; called by muse, mutect2, varscan2
- VNN2 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100426716; called by muse, mutect2
- WDR26 | c.2013T>A p.F671L (on ENST00000414423 / NM_001379403.1; = p.F571L on NM_025160.7) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.074); catalogued as COSV99690934; called by muse, mutect2, varscan2
- XAB2 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100601523; called by muse, mutect2, varscan2
- XIRP1 | c.2438G>A p.G813E | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs552414287, COSV100453432; called by muse, mutect2, varscan2
- XK | c.113C>G p.A38G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101064552; called by muse, mutect2
- XYLT2 | c.1333A>T p.S445C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99190803; called by muse, mutect2, varscan2
- ZAN | c.2138C>A p.S713Y | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.891); catalogued as COSV100769323; called by muse, mutect2, varscan2
- ZBTB7B | c.685C>T p.H229Y (on ENST00000292176; = p.H263Y on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as COSV99420881; called by muse, mutect2, varscan2
- ZER1 | c.2247G>T p.K749N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.981); catalogued as COSV99401876; called by muse, mutect2, varscan2
- ZFR2 | c.1244G>A p.R415K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.05); catalogued as COSV99507069; called by muse, mutect2, varscan2
- ZNF236 | c.3100A>G p.T1034A | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99469382; called by muse, mutect2, varscan2
- ZNF423 | c.1081C>T p.H361Y (on ENST00000563137 / NM_001379286.1; = p.H353Y on NM_015069.4) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV99280290; called by muse, mutect2, varscan2
- ZNF70 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV100558841; called by muse, mutect2, varscan2
- ZNF91 | c.2771A>T p.H924L | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.463); catalogued as COSV100322319; called by muse, mutect2
- ZSWIM3 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 48/225 reads (21%) | catalogued as COSV99666204; called by muse, mutect2, varscan2
- AGAP1 | c.1009dup p.A337Gfs*13 | Frame Shift Ins (INS) | VAF 21/207 reads (10%) | called by mutect2, pindel, varscan2
- CES3 | c.1270_1288del p.S424Efs*27 | Frame Shift Del (DEL) | VAF 24/202 reads (12%) | called by mutect2, pindel
- DNAJC11 | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, varscan2
- FOLH1 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV2-33 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 80/506 reads (16%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); called by muse, varscan2
- IQGAP3 | c.2315_2325del p.R772Pfs*13 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | called by mutect2, pindel, varscan2
- KCNMB2 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MRC1 | c.2950C>A p.L984M | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PRAMEF20 | c.1261G>T p.V421F | Missense Mutation (SNP) | VAF 63/626 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ZNF236 | c.5239del p.X1747_splice | Splice Site (DEL) | VAF 50/328 reads (15%) | called by mutect2, pindel, varscan2
- ACADVL | c.783C>G p.V261= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV99138366; called by muse, mutect2, varscan2
- ACTN2 | c.642G>T p.L214= | Silent (SNP) | VAF 37/210 reads (18%) | catalogued as COSV100856577, COSV63973833; called by muse, mutect2, varscan2
- ACY3 | c.114C>T p.P38= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1227891989, COSV99662901; called by muse, mutect2, varscan2
- ALPK3 | c.2142G>T p.G714= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99360348; called by muse, mutect2
- ANKRD50 | c.111C>G p.L37= | Silent (SNP) | VAF 17/190 reads (9%) | catalogued as COSV101538895; called by muse, mutect2
- ATP2A1 | c.2751C>A p.S917= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV100706863; called by muse, mutect2, varscan2
- BPIFB3 | c.246C>T p.H82= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as rs780244191, COSV100972308; called by muse, mutect2, varscan2
- CCDC141 | c.3126C>T p.C1042= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as COSV55375738, COSV99836288; called by muse, mutect2
- CEP85L | c.1809A>G p.K603= | Silent (SNP) | VAF 43/217 reads (20%) | catalogued as COSV100874102; called by muse, mutect2, varscan2
- CLCNKB | c.1668C>T p.T556= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as rs776671813, COSV100989649; called by muse, mutect2, varscan2
- CLSTN2 | c.876G>T p.V292= | Silent (SNP) | VAF 72/417 reads (17%) | catalogued as COSV101515564; called by muse, mutect2, varscan2
- CRB1 | c.1749C>A p.I583= | Silent (SNP) | VAF 34/200 reads (17%) | catalogued as rs1178650450, COSV100957708, COSV66329368; called by muse, mutect2, varscan2
- DZANK1 | c.1407C>G p.L469= (on ENST00000262547 / NM_001099407.1; = p.L276= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/400 reads (19%) | catalogued as COSV99361988; called by muse, mutect2, varscan2
- E2F7 | c.1149A>G p.A383= | Silent (SNP) | VAF 34/183 reads (19%) | catalogued as COSV100523353; called by muse, mutect2, varscan2
- FBXO7 | c.1383C>T p.I461= | Silent (SNP) | VAF 49/243 reads (20%) | catalogued as COSV99832502; called by muse, mutect2, varscan2
- GABRA2 | c.237T>C p.P79= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as COSV100733910; called by muse, mutect2
- GALNT17 | c.1602G>T p.R534= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV61150295; called by muse, mutect2
- GRIN2B | c.786G>T p.V262= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs1339585240, COSV101662939; called by muse, mutect2, varscan2
- HIPK4 | c.813C>T p.A271= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as rs771130701, COSV99396273; called by muse, mutect2
- HTR1B | c.336C>G p.T112= | Silent (SNP) | VAF 10/151 reads (7%) | catalogued as COSV100885352; called by muse, mutect2
- KCNA1 | c.1098G>A p.A366= | Silent (SNP) | VAF 65/450 reads (14%) | catalogued as COSV66836738, COSV66837556; called by muse, mutect2, varscan2
- KCNA6 | c.273C>A p.P91= | Silent (SNP) | VAF 27/164 reads (16%) | catalogued as COSV54973808; called by muse, mutect2, varscan2
- KCNJ3 | c.279G>T p.V93= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as COSV99715372; called by muse, mutect2, varscan2
- KCNMB2 | c.672C>A p.S224= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as COSV100843854; called by muse, mutect2, varscan2
- KIAA1755 | c.3369A>G p.A1123= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99641593; called by muse, mutect2, varscan2
- KIR3DL1 | c.903C>A p.P301= | Silent (SNP) | VAF 90/451 reads (20%) | called by muse, mutect2
- KNDC1 | c.477G>A p.A159= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs761257041, COSV100463630; called by muse, varscan2
- MIS18BP1 | c.267T>C p.S89= | Silent (SNP) | VAF 20/222 reads (9%) | catalogued as COSV100172737; called by muse, mutect2
- NCOR2 | c.969G>T p.R323= | Silent (SNP) | VAF 28/258 reads (11%) | catalogued as COSV100656973; called by muse, mutect2, varscan2
- OR10K2 | c.351C>A p.V117= | Silent (SNP) | VAF 16/196 reads (8%) | catalogued as rs762529314, COSV100149409, COSV100149637; called by muse, mutect2
- OR10Z1 | c.495C>T p.H165= | Silent (SNP) | VAF 38/157 reads (24%) | catalogued as COSV100778953; called by muse, mutect2, varscan2
- OR2T10 | c.756T>C p.Y252= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs758843051, COSV100393598; called by muse, mutect2, varscan2
- OR6M1 | c.849C>T p.N283= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as rs894871686, COSV100484026; called by muse, mutect2
- OR8G2P | c.45T>A p.A15= | Silent (SNP) | VAF 14/104 reads (13%) | called by muse, varscan2
- PCDHB12 | c.1362T>G p.T454= | Silent (SNP) | VAF 32/189 reads (17%) | catalogued as COSV53399826, COSV99506875; called by muse, mutect2, varscan2
- PDYN | c.528G>A p.G176= | Silent (SNP) | VAF 36/236 reads (15%) | catalogued as COSV99452741; called by muse, mutect2, varscan2
- PLEKHG1 | c.2253G>A p.P751= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs144500507; called by muse, mutect2, varscan2
- PNLIP | c.171A>G p.L57= | Silent (SNP) | VAF 31/187 reads (17%) | catalogued as COSV100981656; called by muse, mutect2, varscan2
- PRAMEF18 | c.270C>G p.A90= | Silent (SNP) | VAF 24/584 reads (4%) | catalogued as rs1420029606; called by muse, mutect2
- PRAMEF2 | c.1131C>A p.S377= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as COSV99534947; called by muse, mutect2, varscan2
- PRR14 | c.1461A>G p.Q487= | Silent (SNP) | VAF 30/174 reads (17%) | catalogued as COSV99788305; called by muse, mutect2, varscan2
- SIN3B | c.1857G>A p.L619= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as COSV99931463; called by muse, mutect2, varscan2
- SLC25A10 | c.660G>T p.L220= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100518954; called by muse, mutect2
- SPIN4 | c.24G>A p.P8= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV58737769; called by muse, mutect2
- TASOR | c.1887T>G p.L629= (on ENST00000355628 / NM_001365636.2; = p.L233= on NM_015224.3) | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV100843376; called by muse, mutect2, varscan2
- TBC1D17 | c.1047C>T p.R349= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99680465; called by muse, mutect2, varscan2
- TMTC1 | c.2442G>T p.V814= (on ENST00000539277 / NM_001193451.2; = p.V706= on NM_175861.3) | Silent (SNP) | VAF 59/328 reads (18%) | catalogued as COSV55488098, COSV99761450; called by muse, mutect2, varscan2
- TNXB | c.10815G>T p.L3605= (on ENST00000647633; = p.L3358= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as COSV100925983, COSV64490544; called by muse, mutect2, varscan2
- TPD52L2 | c.201G>T p.L67= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99410548; called by muse, mutect2, varscan2
- XPNPEP2 | c.1321C>T p.L441= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV100941423, COSV64369998; called by muse, mutect2, varscan2
- ZBTB49 | c.1467T>C p.S489= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV100552379; called by muse, mutect2
- ZNF180 | c.24G>T p.T8= | Silent (SNP) | VAF 72/373 reads (19%) | catalogued as rs1255283993, COSV99659644; called by muse, mutect2, varscan2
- DUSP13 | c.*870G>T | 3'UTR (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100403298; called by muse, mutect2, varscan2
- MIR412 | n.69C>A | RNA (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2, varscan2
